National Lung Screening Trial (NLST) participant 214655 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 59 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 10): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 50 mA, display field of view 35 cm, reconstruction filter GE Bone / GE Standard.
- T1 (day 345): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 25 effective mAs, display field of view 32 cm, reconstruction filter Siemens B50F / Siemens B30.
- T2 (day 737): Positive, no significant change: stable abnormalities potentially related to lung cancer, unchanged since the prior screening exam. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 25 effective mAs, display field of view 32 cm, reconstruction filter Siemens B50F / Siemens B30.

Abnormalities recorded by the reading radiologist on the CT screens (14 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 11 mm, longest perpendicular diameter 9 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 161; whether pre-existing could not be determined.
- T0 abnormality 2: Pleural thickening or effusion.
- T0 abnormality 3: Emphysema; pre-existing on earlier images (earliest visible 1,132 days before randomisation); interval change does not warrant further investigation.
- T0 abnormality 4: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar; pre-existing on earlier images (earliest visible 1,132 days before randomisation); interval change does not warrant further investigation.
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 13 mm, longest perpendicular diameter 10 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 106; new (not pre-existing on earlier images).
- T1 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 16 mm, longest perpendicular diameter 13 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 88; pre-existing on earlier images (earliest visible day 13); no interval growth; no suspicious change in attenuation.
- T1 abnormality 3: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar; pre-existing on earlier images (earliest visible day 13); interval change does not warrant further investigation.
- T1 abnormality 4: Emphysema.
- T1 abnormality 5: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 13 mm, longest perpendicular diameter 12 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 114; new (not pre-existing on earlier images).
- T2 abnormality 2: Emphysema.
- T2 abnormality 3: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 4: Other potentially significant abnormality above the diaphragm.
- T2 abnormality 5: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 7 mm, longest perpendicular diameter 7 mm; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 96; identified only on comparison with prior images.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,561.
